Gene-level copy-number profile of tumor specimen C3L-02212-01 from CPTAC case C3L-02212, project CPTAC-3 (Kidney — Transitional Cell Papillomas and Carcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Urothelial carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 70.5 years (25,745 days).
Specimen C3L-02212-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 0fb271f2-43af-4448-9eb7-6d0e492e2ae8.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-02212-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,711 have no estimate.
https://portal.gdc.cancer.gov/files/73167e9e-43bb-4753-8617-4d58e3b0b3b3

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 32; copy number 2: 4,221; copy number 3: 3,042; copy number 4: 49,395; copy number 5: 320; copy number 6: 1,802; copy number 7: 100.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 32. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
